Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A45I, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A45I-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

THYROID, TOTAL THYROIDECTOMY (15 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, LOCATED IN THE RIGHT LOBE (2.1 M) AND LEFT LOBE (0.3 CM).
- B. 2.1 CM FOCUS IS TALL CELL VARIANT WITH EXTRATHYROIDAL EXTENSION AND EXTENSION TO RESECTION MARGIN. *> 50% tall cell variant, per ISS.*
- C. NO ANGIOLYMPHATIC INVASION.
- D. FIVE RIGHT PARATHYROIDAL AND ONE LEFT PARATHYROIDAL LYMPH NODES, FREE OF TUMOR (0/6).
- E. PATHOLOGIC STAGE: pT3, N0.
- F. NODULAR THYROID HYPERPLASIA WITH CHRONIC LYMPHOCYTIC THYROIDITIS.

Addendum

Prior molecular testing of Right Thyroid, Fine Needle Aspiration () identified a **BRAF** mutation. Therefore, molecular testing was not repeated on the total thyroidectomy specimen.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:

TUMOR SITE:

TUMOR FOCALITY:

TUMOR SIZE (largest nodule):

HISTOLOGIC TYPE**:

PRIMARY TUMOR (pT):

REGIONAL LYMPH NODES (pN):

Total Thyroidectomy

Right Lobe, Left Lobe

Multifocal

Greatest Dimension: 2.1 cm

Papillary carcinoma, tall cell variant

pT3

pN0

Number of regional lymph nodes examined: 6

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM):

EXTRATHYROIDAL EXTENSION:

MARGINS:

LYMPH-VASCULAR INVASION:

ADDITIONAL PATHOLOGIC FINDINGS:

Not applicable

Present

Margin(s) involved by carcinoma

Not identified

Thyroiditis

Other: Nodular thyroid.

ICD-O-3

carcinoma, papillary, tall cell variant 8344/3

Site: thyroid, NOS C73.9 lw
9/25/12

Source: NCI Genomic Data Commons file b4944253-a15b-4ebf-b27c-432b7695452f (TCGA-BJ-A45I.AD17A97F-3FB4-4D09-8F84-97BEBD06DB0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).